Somatic mutation profile of tumor specimen TCGA-CR-7368-01A (aliquot TCGA-CR-7368-01A-11D-2129-08) from TCGA case TCGA-CR-7368, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.4 years (19,876 days).
Specimen TCGA-CR-7368-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c594d31c-cd42-4224-bcb9-70b01fb2ec64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7368-10A (Blood Derived Normal), aliquot TCGA-CR-7368-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b24b1509-fc77-413f-8a64-8f38f2dd5d46

The open-access MAF lists 218 somatic variants for this specimen: 163 protein-altering or splice-affecting, 52 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 52, Nonsense Mutation 10, Splice Site 6, Frame Shift Del 4, Frame Shift Ins 2, 3'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.385-1G>A p.X129_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | hotspot (GDC flag); catalogued as COSV100938553, COSV65038249; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs202028007, COSV99699353; called by muse, mutect2, varscan2
- ACADVL | c.1270-1G>A p.X424_splice | Splice Site (SNP) | VAF 27/78 reads (35%) | catalogued as COSV99138830; called by muse, mutect2, varscan2
- ACER3 | c.497+2T>C p.X166_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99568838; called by muse, mutect2, varscan2
- ACSS1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV100054022; called by muse, mutect2
- ADAMTS4 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100917564; called by muse, mutect2, varscan2
- ADIG | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 45/96 reads (47%) | catalogued as COSV53434537; called by muse, mutect2, varscan2
- AHCYL2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs746525069, COSV100273212; called by muse, mutect2, varscan2
- AHNAK2 | c.3722G>T p.G1241V | Missense Mutation (SNP) | VAF 75/111 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100318837; called by muse, mutect2, varscan2
- ANGPTL7 | c.20C>G p.S7* | Nonsense Mutation (SNP) | VAF 19/166 reads (11%) | catalogued as COSV100816631; called by muse, mutect2, varscan2
- ANK3 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55050694, COSV55076066; called by muse, mutect2, varscan2
- ANKAR | c.1432C>G p.Q478E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV99854599; called by muse, mutect2
- ANO5 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100202198, COSV61088048; called by muse, mutect2, varscan2
- APBB1IP | c.194A>G p.D65G | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100774461; called by muse, mutect2, varscan2
- ARID5B | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV54418922, COSV99690376; called by muse, mutect2, varscan2
- ATG2B | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100738221; called by muse, varscan2
- ATMIN | c.1094G>C p.S365T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100214766, COSV55146306; called by muse, mutect2, varscan2
- ATP6V1G3 | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99811041; called by muse, mutect2, varscan2
- BIN3 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV99374305; called by muse, mutect2, varscan2
- C1orf56 | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV99764785; called by muse, mutect2, varscan2
- C4BPA | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs374378424, COSV100891278; called by muse, mutect2, varscan2
- CAPN7 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.117); catalogued as COSV99513014; called by muse, mutect2, varscan2
- CBWD6 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.826); catalogued as rs777525282; called by muse, mutect2, varscan2
- CCDC125 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV101143735; called by muse, mutect2, varscan2
- CD109 | c.3001C>G p.P1001A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV99754478; called by muse, mutect2, varscan2
- CD80 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99956177, COSV99956292; called by muse, mutect2, varscan2
- CLIP1 | c.3518C>A p.S1173* (on ENST00000620786 / NM_001247997.1; = p.S1162* on NM_002956.2) | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100212315, COSV56799753; called by muse, mutect2, varscan2
- CMYA5 | c.6115A>G p.K2039E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs375929849; called by muse, mutect2, varscan2
- CNR1 | c.1145G>T p.C382F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100759340; called by muse, mutect2, varscan2
- COL1A2 | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV99800949; called by muse, mutect2, varscan2
- COL5A1 | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 77/143 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100880379, COSV100880548; called by muse, mutect2, varscan2
- CSPP1 | c.1442A>G p.E481G (on ENST00000676605; = p.E440G on NM_024790.6) | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV99139799; called by muse, mutect2, varscan2
- CTTNBP2 | c.1591A>T p.T531S | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.259); catalogued as COSV99354770; called by muse, mutect2, varscan2
- CUX2 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs749496376, COSV99920658; called by muse, mutect2, varscan2
- CYP2R1 | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100584993; called by muse, mutect2, varscan2
- CYP4F8 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100358235; called by muse, mutect2, varscan2
- DCTN6 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV99645151; called by muse, mutect2, varscan2
- DDR2 | c.2526C>G p.F842L | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906792, COSV63375295; called by muse, mutect2
- DIAPH3 | c.1426G>T p.D476Y (on ENST00000400324 / NM_001042517.2; = p.D213Y on NM_030932.3) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs911849667, COSV57366101; called by muse, mutect2, varscan2
- DMTF1 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.085); catalogued as COSV100487494; called by muse, mutect2, varscan2
- DNAJC13 | c.2629C>T p.L877F | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV99608018; called by muse, mutect2, varscan2
- DNAJC6 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99675574; called by muse, mutect2
- DNTTIP2 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100785212; called by muse, mutect2, varscan2
- DSG2 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99853525; called by muse, mutect2, varscan2
- EGFLAM | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100380735; called by muse, mutect2, varscan2
- EOLA2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs782633393, COSV100778119; called by muse, mutect2, varscan2
- EVC | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs930402783, COSV99382250, COSV99382482; called by muse, mutect2, varscan2
- FAM120A | c.1670G>C p.R557T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV99466552; called by muse, mutect2, varscan2
- FAM120A | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs762770311, COSV99466555; called by muse, mutect2, varscan2
- FANCA | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1388498490, COSV101225212; called by muse, mutect2, varscan2
- FAP | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs780875561, COSV51861858; called by muse, mutect2, varscan2
- FASTKD3 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99242074; called by muse, mutect2
- FAT3 | c.13408G>A p.E4470K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs753317758, COSV53114577; called by muse, mutect2, varscan2
- FBH1 | c.1369C>T p.Q457* (on ENST00000362091 / NM_178150.3; = p.Q508* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100758926; called by muse, mutect2
- FDCSP | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV100525846; called by muse, mutect2, varscan2
- FHDC1 | c.2738G>A p.R913K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV99471674; called by muse, mutect2, varscan2
- FLG2 | c.5438C>T p.S1813L | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as COSV101166181; called by muse, mutect2, varscan2
- FURIN | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs769907195, COSV99184777; called by mutect2, varscan2
- FYN | c.309T>A p.F103L | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.774); catalogued as COSV99992419; called by muse, mutect2
- G3BP2 | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100693008; called by muse, mutect2, varscan2
- GABPA | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1259051985, COSV61395539; called by muse, mutect2, varscan2
- GABRA1 | c.1052C>A p.P351Q | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.438); catalogued as COSV99196247; called by muse, mutect2, varscan2
- GNAT2 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as COSV100655901; called by muse, mutect2, varscan2
- GNB5 | c.257G>A p.R86Q (on ENST00000261837 / NM_016194.4; = p.R44Q on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs776406670, COSV55900685; called by muse, mutect2
- HKDC1 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100664755; called by muse, mutect2, varscan2
- HOOK2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751125633, COSV99317301; called by muse, mutect2, varscan2
- IFIT1B | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100879109; called by muse, mutect2, varscan2
- IFNA8 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV66504656; called by muse, mutect2, varscan2
- IGSF1 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100812290; called by muse, mutect2, varscan2
- INTS5 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1478186299, COSV100399795; called by muse, mutect2, varscan2
- ITCH | c.1345G>A p.D449N (on ENST00000262650 / NM_001257137.3; = p.D408N on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99393120; called by muse, mutect2
- ITGA2 | c.2770A>T p.N924Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99671528; called by muse, mutect2, varscan2
- KAT6A | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as COSV99705816; called by muse, mutect2
- KATNIP | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs779040410, COSV55179977; called by muse, varscan2
- KCNS3 | c.884T>G p.M295R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100411422; called by muse, mutect2, varscan2
- KDM4A | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); catalogued as COSV100969640; called by muse, mutect2, varscan2
- KIF14 | c.3421G>C p.E1141Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100951058; called by muse, mutect2, varscan2
- KRTAP13-2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV101299669; called by muse, mutect2, varscan2
- LCMT2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV59790628; called by muse, mutect2, varscan2
- LDOC1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.47); PolyPhen benign (0.312); catalogued as COSV100983197; called by muse, mutect2, varscan2
- LIFR | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99665368; called by muse, mutect2
- LMNTD1 | c.147T>A p.Y49* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99280288; called by muse, mutect2, varscan2
- LMOD1 | c.1465A>C p.K489Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100939262; called by muse, mutect2, varscan2
- LRRTM1 | c.870C>A p.N290K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99703092; called by muse, mutect2, varscan2
- MAFB | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV64826581; called by muse, mutect2, varscan2
- MAMDC4 | c.1975G>A p.E659K (on ENST00000445819; = p.E580K on NM_206920.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100440578; called by muse, mutect2, varscan2
- MASTL | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs760390710, COSV100668954, COSV60911779; called by muse, mutect2, varscan2
- MFSD8 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99614675; called by muse, mutect2, varscan2
- MKRN3 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV100091584; called by muse, mutect2, varscan2
- MTMR8 | c.1123A>T p.I375L | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.88); PolyPhen benign (0.107); catalogued as COSV100878572; called by muse, mutect2, varscan2
- MTR | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100855534; called by muse, mutect2, varscan2
- MUC5B | c.12385G>C p.E4129Q | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV101500724; called by muse, mutect2, varscan2
- MYF5 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV99953389; called by muse, mutect2, varscan2
- MYO5A | c.5191C>G p.R1731G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100698123; called by muse, mutect2
- MYT1 | c.3184G>T p.G1062C | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100115351, COSV60502280; called by muse, mutect2, varscan2
- NEFM | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV99647548; called by muse, mutect2
- NELL2 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408624987, COSV100420708, COSV61572812; called by muse, mutect2
- NFYC | c.886-1G>A p.X296_splice (on ENST00000308733 / NM_001308114.1; = p.X277_splice on NM_014223.5) | Splice Site (SNP) | VAF 10/119 reads (8%) | catalogued as COSV100438581, COSV100438714; called by muse, mutect2
- NPAS4 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV100215224; called by muse, mutect2, varscan2
- NPTX2 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99675075; called by muse, varscan2
- ODF2L | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99644669; called by muse, mutect2
- OR10AG1 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV100400191; called by muse, mutect2, varscan2
- OR2M2 | c.490T>C p.F164L | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100677313; called by muse, mutect2, varscan2
- OR4B1 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs780047019, COSV100535710, COSV58883728; called by muse, mutect2, varscan2
- OR6T1 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100190167; called by muse, mutect2, varscan2
- PCDHB6 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99171041; called by muse, mutect2, varscan2
- PCDHGB4 | c.1187C>G p.S396* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99546167; called by muse, mutect2
- PLCL1 | c.1645G>C p.D549H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV70821223; called by muse, mutect2, varscan2
- PODXL2 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV100686580; called by muse, mutect2, varscan2
- POLK | c.1038C>G p.I346M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV54037960, COSV99606429; called by muse, mutect2, varscan2
- PPP2R3B | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1398906777, COSV66813263; called by muse, mutect2, varscan2
- PRDM10 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as rs1400273941, COSV100457012; called by muse, mutect2, varscan2
- PRICKLE2 | c.2050A>T p.I684F (on ENST00000295902; = p.I628F on NM_198859.4) | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.139); catalogued as COSV99897996; called by muse, mutect2, varscan2
- RAB23 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100443874; called by muse, mutect2
- RB1CC1 | c.2599C>G p.L867V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.317); catalogued as COSV99212461, COSV99212894; called by muse, mutect2, varscan2
- RBM18 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.099); catalogued as COSV101313800, COSV69874339; called by muse, mutect2, varscan2
- RBM28 | c.1290G>C p.K430N | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99775899; called by muse, mutect2, varscan2
- RESF1 | c.1967C>T p.S656L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100440582; called by muse, mutect2
- REV3L | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as COSV100725661; called by muse, mutect2, varscan2
- RGP1 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV100960342; called by muse, mutect2
- RICTOR | c.4838G>A p.R1613H | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57126551; called by muse, mutect2, varscan2
- RUNDC3B | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55952598, COSV99714222; called by muse, mutect2, varscan2
- SAT1 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV100803909; called by muse, mutect2, varscan2
- SATB1 | c.2098C>G p.L700V | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58671463; called by muse, mutect2
- SCN8A | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV61980842; called by muse, mutect2
- SEMA5A | c.2774C>A p.P925H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV101227727, COSV101228693; called by muse, mutect2, varscan2
- SH3KBP1 | c.1494+1G>A p.X498_splice | Splice Site (SNP) | VAF 6/96 reads (6%) | catalogued as COSV101116397; called by muse, mutect2
- SIK3 | c.2935C>G p.Q979E (on ENST00000445177 / NM_001366686.2; = p.Q937E on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.298); catalogued as COSV99408748; called by muse, mutect2, varscan2
- SLC16A4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as rs1340562486, COSV100873008; called by muse, mutect2, varscan2
- SLC26A5 | c.2017T>C p.Y673H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV100100110; called by muse, mutect2, varscan2
- SNRK | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV99939374; called by muse, mutect2, varscan2
- SPEG | c.8398C>T p.P2800S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs776744750, COSV100405543; called by muse, mutect2
- ST8SIA2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | PolyPhen probably damaging (0.997); catalogued as rs1232323398, COSV51568606; called by muse, mutect2
- STRN | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV99815683; called by muse, mutect2
- SYNE1 | c.3484G>C p.E1162Q (on ENST00000367255 / NM_182961.4; = p.E1169Q on NM_033071.3) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99577011; called by muse, mutect2, varscan2
- TEAD1 | c.180A>T p.L60F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV100532829; called by muse, mutect2, varscan2
- TEX47 | c.140T>A p.L47H | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99787388; called by muse, mutect2
- TRMT10A | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as COSV99911045; called by muse, mutect2, varscan2
- TSKS | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99883660; called by muse, mutect2, varscan2
- TTN | c.8422G>C p.E2808Q (on ENST00000591111; = p.E2762Q on NM_003319.4) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | PolyPhen benign (0.346); catalogued as COSV100628125, COSV60070729; called by muse, mutect2, varscan2
- TVP23B | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs758025427; called by muse, mutect2, varscan2
- UBXN4 | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV99739568; called by muse, mutect2, varscan2
- UGT1A10 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as COSV60838598; called by muse, mutect2, varscan2
- USP34 | c.9379A>G p.S3127G | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV101277198; called by muse, mutect2, varscan2
- VIRMA | c.4798A>G p.I1600V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.927); catalogued as COSV52583072; called by muse, mutect2, varscan2
- VPS13D | c.3461G>A p.G1154E | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99169311; called by muse, mutect2
- XYLT2 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99191095; called by muse, mutect2
- ZC3HAV1 | c.377T>A p.L126H | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99649043; called by muse, mutect2, varscan2
- ZKSCAN4 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV101043556; called by muse, mutect2, varscan2
- ZNF211 | c.949G>A p.E317K (on ENST00000347302 / NM_198855.4; = p.E330K on NM_006385.5) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.564); catalogued as COSV99560476; called by muse, mutect2, varscan2
- ZNF266 | c.64T>A p.S22T | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100749442; called by muse, mutect2, varscan2
- ZNF274 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100465463; called by muse, mutect2, varscan2
- ZNF292 | c.6262G>C p.E2088Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100371141; called by muse, varscan2
- ZNF75D | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as rs1012574761, COSV100883694; called by muse, mutect2
- ZNFX1 | c.5714C>T p.A1905V | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100872604; called by muse, mutect2, varscan2
- AHNAK2 | c.8021_8022del p.S2674* | Frame Shift Del (DEL) | VAF 53/267 reads (20%) | called by mutect2, pindel, varscan2
- ARL6IP6 | c.141del p.C48Afs*83 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- DNM2 | c.691_699dup p.X231_splice | Splice Site (INS) | VAF 19/59 reads (32%) | called by mutect2, varscan2
- ITGB1 | c.2165_2166del p.E722Vfs*37 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by pindel, varscan2
- SLC7A5 | c.635dup p.L213Pfs*11 | Frame Shift Ins (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- URI1 | c.1584del p.A529Pfs*21 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel, varscan2
- ZNF750 | c.105dup p.E36* | Frame Shift Ins (INS) | VAF 57/105 reads (54%) | called by mutect2, pindel, varscan2
- ABCB5 | c.1227C>G p.L409= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99329459; called by muse, mutect2
- ABCG8 | c.921C>T p.I307= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs780422381, COSV55394886; called by muse, mutect2, varscan2
- ABLIM3 | c.1176C>T p.S392= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV100448767; called by muse, mutect2, varscan2
- AHNAK2 | c.3723C>T p.G1241= | Silent (SNP) | VAF 75/111 reads (68%) | catalogued as rs1309960567, COSV100318833; called by muse, mutect2, varscan2
- APOBEC3H | c.414C>T p.F138= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs775553421, COSV100818870; called by muse, mutect2, varscan2
- ATP2C1 | c.2115C>T p.F705= | Silent (SNP) | VAF 9/205 reads (4%) | catalogued as COSV60759593; called by muse, mutect2
- CA14 | c.519T>G p.A173= | Silent (SNP) | VAF 61/162 reads (38%) | catalogued as COSV99354506; called by muse, mutect2, varscan2
- CAPNS2 | c.564A>G p.Q188= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as COSV100045273; called by muse, mutect2, varscan2
- CATSPERD | c.1242G>A p.S414= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as rs553271657, COSV58466050; called by muse, mutect2, varscan2
- CFH | c.1014G>A p.E338= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100661620; called by muse, mutect2, varscan2
- CNTN6 | c.936C>G p.L312= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100611787, COSV63182123; called by muse, mutect2, varscan2
- COLEC12 | c.42C>T p.F14= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs778096255, COSV68375160; called by muse, mutect2, varscan2
- CSF2RA | c.426G>A p.P142= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as rs770309852, COSV62624990; called by muse, mutect2, varscan2
- DDX23 | c.2130C>G p.L710= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV99975098; called by muse, mutect2, varscan2
- EBF3 | c.1140G>A p.L380= (on ENST00000355311 / NM_001375392.1; = p.L371= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100799584; called by muse, mutect2, varscan2
- FCGBP | c.9030C>T p.G3010= | Silent (SNP) | VAF 50/546 reads (9%) | catalogued as rs766486146; called by muse, mutect2
- GOLGA8G | c.1344G>A p.E448= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100284668, COSV61551307; called by mutect2, varscan2
- HS3ST5 | c.528C>T p.I176= | Silent (SNP) | VAF 46/309 reads (15%) | catalogued as rs778244737, COSV100451336; called by muse, mutect2, varscan2
- LMAN1L | c.45C>G p.L15= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV100547830; called by muse, mutect2, varscan2
- LMAN1L | c.159C>T p.F53= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV59003189; called by muse, mutect2, varscan2
- MAP2K2 | c.585G>C p.V195= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99502693; called by muse, mutect2, varscan2
- MAP4 | c.1590C>T p.L530= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as rs766316098, COSV100806289; called by muse, mutect2, varscan2
- MFSD6L | c.459C>T p.F153= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV100266846; called by muse, mutect2, varscan2
- MICALL1 | c.1590G>A p.P530= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs138192828; called by muse, mutect2, varscan2
- MOS | c.912C>T p.F304= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100322934, COSV100323016; called by muse, mutect2, varscan2
- MTMR9 | c.1089C>T p.A363= | Silent (SNP) | VAF 53/170 reads (31%) | catalogued as COSV99644570; called by muse, mutect2, varscan2
- MYO18A | c.2202G>A p.E734= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs752509448, COSV100572675, COSV62866604; called by muse, mutect2, varscan2
- MYO1F | c.354G>C p.V118= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100597040; called by muse, mutect2
- NOTCH4 | c.3969G>C p.L1323= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs1295325827, COSV100900975; called by muse, mutect2
- OR2T2 | c.579G>A p.T193= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs564223502, COSV100737773; called by muse, mutect2, varscan2
- PADI3 | c.1878C>G p.L626= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100968589; called by muse, mutect2, varscan2
- PCDHA2 | c.1353C>T p.N451= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as rs376199248; called by muse, mutect2, varscan2
- PIGA | c.339C>T p.L113= | Silent (SNP) | VAF 47/58 reads (81%) | catalogued as COSV100363527; called by muse, mutect2, varscan2
- PIP5K1B | c.1557G>A p.L519= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as COSV99599703; called by muse, mutect2
- PKHD1 | c.4278G>A p.S1426= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs745566730, COSV100584439; called by muse, mutect2, varscan2
- PLIN4 | c.2115G>A p.V705= (on ENST00000301286; = p.V720= on NM_001367868.2) | Silent (SNP) | VAF 36/524 reads (7%) | catalogued as rs1319846292, COSV100014067; called by muse, mutect2
- PREP | c.183C>G p.L61= (on ENST00000369110; = p.L127= on NM_002726.5) | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100964115; called by muse, mutect2, varscan2
- PURG | c.372G>A p.E124= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as rs1311456823, COSV99989790; called by muse, mutect2, varscan2
- RANBP3L | c.1299C>T p.C433= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs769576272, COSV56955051; called by muse, mutect2, varscan2
- RASSF8 | c.225C>G p.L75= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV99280957; called by muse, mutect2, varscan2
- RDH13 | c.516C>G p.L172= (on ENST00000415061 / NM_001145971.2; = p.L101= on NM_138412.4) | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV99401620; called by muse, mutect2
- RIN3 | c.1518T>A p.S506= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV99379966; called by muse, mutect2, varscan2
- SLC35F2 | c.669G>A p.L223= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99758855; called by muse, mutect2
- SMC3 | c.2016G>A p.R672= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV100700042; called by muse, mutect2, varscan2
- SNX5 | c.135C>G p.V45= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100899083; called by muse, mutect2, varscan2
- SV2C | c.597C>T p.L199= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs1292080692, COSV100456769; called by muse, mutect2
- TRAV10 | c.240C>T p.N80= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs189035449; called by muse, mutect2, varscan2
- TRIAP1 | c.186G>A p.L62= | Silent (SNP) | VAF 35/218 reads (16%) | catalogued as COSV99984904; called by muse, mutect2, varscan2
- TTL | c.315C>G p.L105= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99271582; called by muse, mutect2, varscan2
- UBA6 | c.408A>T p.T136= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV100451862; called by muse, mutect2, varscan2
- XIRP2 | c.5328T>G p.A1776= (on ENST00000628543; = p.A1951= on NM_152381.6) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99746915; called by muse, mutect2, varscan2
- ZNF280A | c.366A>G p.E122= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV100131233; called by muse, mutect2, varscan2
- CD46 | c.*118G>C | 3'UTR (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100523068; called by muse, mutect2, varscan2
- DOT1L | c.4606+1015C>G | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, varscan2
- IGKV1-13 | n.114G>A | RNA (SNP) | VAF 6/40 reads (15%) | catalogued as rs1398481424; called by mutect2, varscan2
